Surgical pathology report (de-identified scan), TCGA case TCGA-G4-6293, project TCGA-COAD (Colon Adenocarcinoma), tissue source site Roswell Park, specimen TCGA-G4-6293-01A (Primary Tumor).

[page 1 of 2]
SPECIMENS:

A. RIGHT COLON & TERMINAL ILEUM

DIAGNOSIS:

RIGHT COLON AND TERMINAL ILEUM, RESECTION (RIGHT HEMICOLECTOMY SPECIMEN):

EXOPHYTIC INVASIVE MODERATELY DIFFERENTIATED ADENOCARCINOMA ARISING FROM TUBULOVILLOUS ADENOMA OF TRANSVERSE COLON WITH FULL MUSCLE WALL THICKNESS INVASION, EXTENSION TO SUBSEROUSAL FAT AND METASTASES TO ONE OUT OF TWENTY SIX PERICOLIC LYMPH NODES (1/26).

-SIZE OF TUMOR - 5.5x3.5x1.0 cm.

-PROXIMAL, DISTAL AND RADIAL MARGINS OF RESECTION - FREE OF TUMOR.

-APPENDIX - NO SPECIFIC PATHOLOGIC CHANGES - NEGATIVE FOR TUMOR.

-PORTION OF OMENTAL FAT - NO SPECIFIC PATHOLOGIC CHANGES.

GI Cancer Template

Tumor Size (cm): 5.5x3.5x1.0 cm.

Grade/Differentiation: G2 moderate

Invasion Depth: Subserosa (not to perit. Surface)

Invasion Vasc/Lymphatic: absent

Invasion Perineural: absent

Extension to adjacent areas: no

Margins: free

Lymph nodes: N1=Positive (1/26)

Stage, Pathology: pT3 N1

Implants: absent

Precursor: present - tubulovillous adenoma

Non-neoplastic areas: NA

SPECIMEN(S):

A. RIGHT COLON & TERMINAL ILEUM

CLINICAL HISTORY:

Colon ca.

GROSS DESCRIPTION:

RIGHT COLON AND TERMINAL ILEUM, RESECTION:

A right hemicolectomy specimen comprised of cecum, ascending and transverse colon and appendix and short segment of terminal ileum. Colon measures 34 cm in length and with internal circumference of 7-9 cm. Short segment of terminal ileum measures 3.5 cm in length.

Situated 5.5 cm from the distal resected margin (transverse colon area) 32 cm from proximal margin is a fungating tumor that occupies 80% of the mucosal circumference. The tumor measures 5.5x3.5x1.0 cm. On sections, tumor grossly infiltrates muscle wall without gross extension to subserosal fat.

Remainder of colonic mucosa is grossly not remarkable. There is no identifiable polyps or diverticuli.

Cecum is not remarkable.

Appendix measures 11 cm in length and external diameter of 0.5 cm. Grossly, appendix is not remarkable.

Attached portion of omentum measures 8x7x0.9 cm. Cut section shows no indurated focus.

Approximately 5 lymph nodes are dissected ranging in size from 0.1 cm to 1x0.5x0.6 cm.

Multiple sections submitted as follows:

A1-A5: tumor

A6: proximal ileal margin

A7: distal colonic margin

A8: representative section of colonic mucosa distal to the tumor

A9: representative section of colonic mucosa proximal to the tumor and ileocecal valve

A11: four lymph nodes from portion near tumor

A12: four lymph nodes from portion near tumor

A13: four lymph nodes from portion near tumor

[page 2 of 2]
[REDACTED]

- A14: one serially sectioned lymph node from portion near tumor
- A15: five lymph nodes from middle portion of colon
- A16: five lymph nodes from middle portion of colon
- A17: one serially sectioned lymph node from middle portion of colon
- A18: five lymph nodes from ileocecal junction
- A19: six lymph nodes from ileocecal junction

ADDENDUM:
ANALYSIS OF MLH1 AND MSH2 PROTEIN EXPRESSION

MLH1 Expression: Present
MSH2 Expression: Present

Tissue from this patient was retrieved from the archive and analyzed for these tumor markers. Expression of MLH1 and MSH2 in the tumor was evaluated by immunohistochemistry. Peritumoral lymphocytes serve as an internal positive control expressing both MLH1 and MSH2.

Testing for Microsatellite Instability has been ordered. The results will be issued in a separate report.

[REDACTED]

[REDACTED]

Source: NCI Genomic Data Commons file 3659a5bb-f284-4936-851a-37b9ce269ef7 (TCGA-G4-6293.5C5A0F9A-E8C8-4B9B-AB34-275B57CBC291.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).